Gene-level copy-number profile of tumor specimen TCGA-D9-A148-06A from TCGA case TCGA-D9-A148, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS.
Specimen TCGA-D9-A148-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.08fc94dd-8d67-46cd-b17b-e256738b3a36.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D9-A148-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0a21086b-09b0-4fea-8a5e-010f0e9e26f8

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 201; copy number 2: 10,878; copy number 3: 14,712; copy number 4: 21,505; copy number 5: 5,664; copy number 6: 4,490; copy number 7: 1,826; copy number 8: 422; copy number 9: 60; copy number 10: 54.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D9-A148-06A-11D-A192-01): tumor purity 0.73, ploidy 3.69, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:109,982,192–110,050,160, 3 genes: RPSAP50, AP001981.1, AP001889.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 114 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:221,418,027–227,817,564, 84 genes, copy number 9–10 (within-gene range 8–10) (broad region; genes not listed).
- chr5:18,547,312–22,853,344, 30 genes, copy number 9 (within-gene range 6–9): RN7SL58P, LINC02100, UBE2V1P12, AC025768.1, AC114981.1, Metazoa_SRP, AC106744.1, AC106744.2, RPL32P14, HSPD1P15, CDH18, AC093303.1, AC094103.1, CDH18-AS1, LINC02146, LINC02241, AC138938.1, AC140168.1, AC140172.1, AC093274.1, GUSBP1, AC138951.1, AC138951.2, AC091946.2, AC091946.1, CDH12, HSPD1P1, AC139497.1, PMCHL1, AC138854.1.

Autosomal genes at a single copy (total copy number 1): 201. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
